Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3862, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3862-01A (Primary Tumor).

Diagnosis:

This is a right-sided hemicolectomy preparation with a moderately differentiated adenocarcinoma (in the ascending colon) of histopathological differentiation grade G2, with erosions of the inner tumor surface, with carcinomatous lymphangitis, with tumor infiltration of the colon wall layers into the pericolic fatty connective tissue with peritumorous chronic recurrent secondary inflammation with an acute inflammatory flare, with focal extracellular mucus formation in the tumor tissue, with tumor-free lymph nodes (0/16) with a moderate chronic lymphadenitis and with tumor-free overview slices from all other resection material portions described. There is also a chronic appendicitis.

According to the section preparations available, the tumor spread of the colon carcinoma corresponds to a tumor stage of pT3, pN0 (0/16), MX, L1, R0.

Tumor classification:

ICDO-DA-M

8140/3, G2

11+

Source: NCI Genomic Data Commons file d081b055-3eb5-428c-8d60-506ece552dc8 (TCGA-AA-3862.422E955E-99A6-42BE-9CD9-0D67F6909C11.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).